Somatic mutation profile of tumor specimen TCGA-RW-A686-01A (aliquot TCGA-RW-A686-01A-11D-A35D-08) from TCGA case TCGA-RW-A686, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 62.2 years (22,718 days).
Specimen TCGA-RW-A686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ddc45d1-d2de-46e2-b9fa-952191a44a9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A686-10A (Blood Derived Normal), aliquot TCGA-RW-A686-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/332a7919-311e-40a6-9a54-01eec39929d5

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, In Frame Del 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITGB1 | c.524_526del p.R175del | In Frame Del (DEL) | VAF 36/110 reads (33%) | catalogued as rs751489253; called by pindel, varscan2
- ABCA12 | c.817T>A p.F273I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- APOL2 | c.392C>G p.T131S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- BCR | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); called by muse, mutect2
- CELSR3 | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- DYSF | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.597); called by mutect2, varscan2
- MRC2 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PCK1 | c.682A>T p.I228F | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEC14L3 | c.728del p.G243Afs*3 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- COASY | c.39G>A p.T13= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as rs1032375730; called by muse, mutect2
